Somatic mutation profile of tumor specimen ALCH-AE7B-TTP1-A (aliquot ALCH-AE7B-TTP1-A-1-0-D-A596-36) from ALCHEMIST case ALCH-AE7B, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 59.6 years (21,784 days).
Specimen ALCH-AE7B-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 82a58557-5149-4540-bc26-79d926014030.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE7B-NB1-A (Blood Derived Normal), aliquot ALCH-AE7B-NB1-A-1-0-D-A596-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e8cb408d-58e0-4ef0-be96-52d201e955fb

The open-access MAF lists 45 somatic variants for this specimen: 31 protein-altering or splice-affecting, 10 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 10, Intron 3, Nonsense Mutation 2, Splice Site 2, Nonstop Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 79/789 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2
- CTNNA2 | c.1051A>C p.N351H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.903); catalogued as rs1185995811, COSV63547281; called by mutect2, varscan2
- DAAM1 | c.3169C>T p.R1057C | Missense Mutation (SNP) | VAF 37/566 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1166170856, COSV62834780; called by muse, mutect2
- DAB2 | c.1213G>T p.G405* | Nonsense Mutation (SNP) | VAF 29/612 reads (5%) | catalogued as COSV100297923; called by muse, mutect2
- FAT1 | c.9215T>G p.L3072R | Missense Mutation (SNP) | VAF 31/372 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV71674686; called by muse, mutect2
- GAB3 | c.1078G>A p.G360S | Missense Mutation (SNP) | VAF 58/251 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV65820355; called by muse, mutect2, varscan2
- MYH15 | c.1867A>C p.K623Q | Missense Mutation (SNP) | VAF 36/399 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV56304456; called by muse, mutect2
- OR51B6 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 25/236 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.893); catalogued as rs751616967; called by mutect2, varscan2
- PCDHB12 | c.1523C>T p.A508V | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as COSV53397189, COSV53401737; called by muse, mutect2
- PHLDB2 | c.1192C>G p.L398V | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as COSV67307788; called by muse, mutect2
- SON | c.3595G>A p.V1199M | Missense Mutation (SNP) | VAF 26/258 reads (10%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.1); catalogued as COSV51652474; called by muse, mutect2, varscan2
- SSRP1 | c.680G>C p.G227A | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53479305; called by muse, mutect2
- ZNF384 | c.1734G>C p.*578Yext*13 (on ENST00000361959; = p.*517Yext*13 on NM_133476.5) | Nonstop Mutation (SNP) | VAF 13/199 reads (7%) | catalogued as COSV58554811, COSV58555081; called by muse, mutect2
- ZNF438 | c.1159C>G p.R387G | Missense Mutation (SNP) | VAF 20/347 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV59200528; called by muse, mutect2
- DYNC1H1 | c.4975G>T p.A1659S | Missense Mutation (SNP) | VAF 37/602 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GDA | c.910T>A p.S304T | Missense Mutation (SNP) | VAF 22/303 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- HEATR9 | c.483A>C p.R161S | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- KANSL1L | c.1790C>G p.T597S | Missense Mutation (SNP) | VAF 25/226 reads (11%) | SIFT tolerated (0.84); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KMT2A | c.8620C>G p.L2874V | Missense Mutation (SNP) | VAF 45/334 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- MATN2 | c.2209G>T p.A737S | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- MCF2L | c.1555A>G p.K519E (on ENST00000375608; = p.K487E on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MOXD1 | c.583C>A p.P195T | Missense Mutation (SNP) | VAF 13/217 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.015); called by muse, mutect2
- PDE4DIP | c.167A>G p.E56G | Missense Mutation (SNP) | VAF 59/524 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RABEP2 | c.607C>A p.P203T | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.522); called by muse, mutect2
- SLC25A31 | c.760-1G>C p.X254_splice | Splice Site (SNP) | VAF 16/132 reads (12%) | called by muse, mutect2, varscan2
- SLC6A13 | c.329T>A p.I110N | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2
- SORCS3 | c.955-1G>T p.X319_splice | Splice Site (SNP) | VAF 48/299 reads (16%) | called by muse, mutect2, varscan2
- SUPT20HL1 | c.2548C>A p.P850T | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- TBXAS1 | c.1134C>A p.H378Q | Missense Mutation (SNP) | VAF 42/555 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.044); called by muse, mutect2
- UBR4 | c.8449G>T p.E2817* | Nonsense Mutation (SNP) | VAF 21/249 reads (8%) | called by muse, mutect2
- ZNF438 | c.1158A>T p.K386N | Missense Mutation (SNP) | VAF 22/352 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- ACTN2 | c.300C>T p.V100= | Silent (SNP) | VAF 44/472 reads (9%) | catalogued as COSV104426764; called by muse, mutect2
- B4GALT6 | c.339T>G p.P113= | Silent (SNP) | VAF 25/236 reads (11%) | called by muse, varscan2
- FAM135B | c.105G>A p.K35= | Silent (SNP) | VAF 12/280 reads (4%) | called by muse, mutect2
- FER1L6 | c.3822G>T p.L1274= | Silent (SNP) | VAF 8/182 reads (4%) | called by muse, mutect2
- NUP188 | c.4752T>C p.A1584= | Silent (SNP) | VAF 6/38 reads (16%) | called by muse, varscan2
- OR8K3 | c.861G>A p.L287= | Silent (SNP) | VAF 36/297 reads (12%) | catalogued as rs1187411521, COSV100449791, COSV57133140; called by muse, mutect2, varscan2
- RUBCN | c.1296T>A p.P432= | Silent (SNP) | VAF 83/568 reads (15%) | called by muse, mutect2, varscan2
- TCAIM | c.429T>C p.T143= | Silent (SNP) | VAF 23/341 reads (7%) | called by muse, mutect2
- TTN | c.12618A>G p.E4206= (on ENST00000591111; = p.E4160= on NM_003319.4) | Silent (SNP) | VAF 39/592 reads (7%) | catalogued as COSV60003557, COSV60326324; called by muse, mutect2
- WASF2 | c.702C>T p.S234= | Silent (SNP) | VAF 58/527 reads (11%) | called by muse, varscan2
- DHCR7 | c.964-76G>A | Intron (SNP) | VAF 4/26 reads (15%) | catalogued as rs923905452; called by muse, varscan2
- LINC01549 | n.380T>G | RNA (SNP) | VAF 12/180 reads (7%) | called by muse, mutect2
- SMARCC1 | c.3043+5950A>T | Intron (SNP) | VAF 22/318 reads (7%) | called by muse, mutect2
- UROC1 | c.903-12G>T | Intron (SNP) | VAF 15/189 reads (8%) | called by muse, mutect2
